Somatic mutation profile of tumor specimen TCGA-06-0188-01A (aliquot TCGA-06-0188-01A-01D-1491-08) from TCGA case TCGA-06-0188, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.4 years (26,080 days).
Specimen TCGA-06-0188-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f6f79ac-52fc-45a1-8b8a-da24a18e6e92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0188-10B (Blood Derived Normal), aliquot TCGA-06-0188-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a079e690-4318-4b3e-bf51-7c1d55700dbc

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 14, Frame Shift Del 3, RNA 2, Nonsense Mutation 2, 5'Flank 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs199633532, CM067634, COSV54368245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 111/206 reads (54%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.920-1G>A p.X307_splice | Splice Site (SNP) | VAF 38/109 reads (35%) | hotspot (GDC flag); catalogued as rs587781702, CS0910927, CS114009, COSV52664150, COSV52690279, COSV52737535; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54695372; called by muse, mutect2, varscan2
- ACSF2 | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 122/345 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); catalogued as rs1432503743, COSV51972169; called by muse, mutect2, varscan2
- ADAMTS19 | c.3106C>T p.R1036C | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs749725000, COSV50744010; called by muse, mutect2, varscan2
- BCORL1 | c.5053G>T p.E1685* | Nonsense Mutation (SNP) | VAF 76/99 reads (77%) | catalogued as COSV54395067; called by muse, mutect2, varscan2
- CNTLN | c.277T>A p.S93T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as COSV99262217; called by muse, mutect2, varscan2
- CNTNAP3 | c.3677G>A p.R1226H | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs753630981; called by muse, mutect2, varscan2
- COL14A1 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs560701039, COSV52850114, COSV52867933; called by muse, mutect2, varscan2
- DECR2 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.075); catalogued as COSV54791323; called by muse, mutect2, varscan2
- DNAJC10 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV51137201; called by muse, mutect2, varscan2
- DPYS | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV100680122, COSV60908155; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 75/404 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as rs745366252; called by muse, mutect2, varscan2
- ITGAM | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs759107498, COSV54933370, COSV54936492; called by muse, mutect2, varscan2
- KLHDC7A | c.1990G>A p.G664S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV68769606, COSV68769892; called by muse, mutect2, varscan2
- LRP2 | c.12493C>T p.R4165C | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs570499038, COSV55543051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LZTR1 | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs776893978, COSV53146917; called by muse, mutect2, varscan2
- MTFR1L | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 120/412 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as COSV65352791; called by muse, varscan2
- MYH8 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 169/272 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs554419599, COSV67963918; called by muse, mutect2, varscan2
- NADK2 | c.1123T>A p.F375I (on ENST00000381937 / NM_001085411.3; = p.F212I on NM_153013.4) | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV56936182; called by muse, mutect2, varscan2
- OR4K5 | c.736del p.V246* | Frame Shift Del (DEL) | VAF 131/715 reads (18%) | catalogued as COSV100262410, COSV60003280; called by mutect2, pindel, varscan2
- OR5C1 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375037936; called by muse, mutect2, varscan2
- PASD1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 72/81 reads (89%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as COSV100949533, COSV64855005; called by muse, mutect2, varscan2
- PRUNE2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745663522, COSV65027512; called by muse, mutect2, varscan2
- PTPRB | c.1122A>C p.R374S | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV54239085; called by muse, mutect2, varscan2
- RIMS2 | c.3352A>G p.N1118D (on ENST00000666250 / NM_001348490.2; = p.K926E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.485); catalogued as rs1193205267, COSV51708011; called by muse, mutect2
- RYR2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs764698152, CM065449, COSV63677117, COSV63693384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SASH1 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as COSV66561139; called by muse, mutect2, varscan2
- SLC5A7 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs748755332, COSV50891064; called by muse, mutect2, varscan2
- TACR3 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 147/384 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs553885967, COSV59197525; called by muse, mutect2, varscan2
- TMPRSS11A | c.954del p.Y319Mfs*14 | Frame Shift Del (DEL) | VAF 100/288 reads (35%) | catalogued as COSV58358008; called by mutect2, pindel, varscan2
- TNC | c.5689G>A p.E1897K | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.908); catalogued as COSV60784112; called by muse, mutect2, varscan2
- TNS1 | c.2311C>T p.H771Y | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.057); catalogued as COSV50699820; called by muse, mutect2, varscan2
- TP53 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1457582183, COSV52745262; called by muse, mutect2, varscan2
- TRAV8-4 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs571719319; called by muse, mutect2, varscan2
- UGT2B11 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71423268; called by muse, mutect2, varscan2
- UGT2B28 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs371664274, COSV59430439; called by muse, mutect2, varscan2
- UMODL1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 55/180 reads (31%) | catalogued as rs776622476, COSV61159902; called by muse, mutect2, varscan2
- AKNA | c.1653G>A p.R551= | Silent (SNP) | VAF 91/177 reads (51%) | catalogued as COSV56312330, COSV99800280; called by muse, mutect2, varscan2
- ATP2A3 | c.1023C>A p.T341= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs768922567, COSV59228458, COSV59229531; called by muse, mutect2, varscan2
- ITGAM | c.741G>A p.K247= | Silent (SNP) | VAF 63/170 reads (37%) | catalogued as COSV54936482; called by muse, mutect2, varscan2
- ITSN1 | c.3792A>G p.Q1264= | Silent (SNP) | VAF 11/151 reads (7%) | catalogued as rs766615959, COSV67157440; called by muse, mutect2
- KHDRBS2 | c.75G>A p.S25= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1267777001, COSV55430587; called by muse, mutect2, varscan2
- KMT2C | c.1227T>C p.C409= | Silent (SNP) | VAF 45/315 reads (14%) | catalogued as COSV51479437; called by muse, mutect2, varscan2
- MAP4K2 | c.600G>C p.L200= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as COSV53642603; called by muse, mutect2, varscan2
- MMP26 | c.699C>T p.H233= | Silent (SNP) | VAF 57/109 reads (52%) | catalogued as rs778728830, COSV56172078; called by muse, mutect2, varscan2
- PABPN1L | c.609C>T p.A203= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs758055343, COSV56351537; called by muse, mutect2, varscan2
- PRPH2 | c.825C>T p.F275= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs201249148, CD972427, COSV57838211; called by muse, mutect2, varscan2
- RAVER1 | c.762G>A p.A254= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs550383395, COSV53344369; called by muse, mutect2, varscan2
- SLC22A5 | c.1353C>T p.A451= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as rs374662740; called by muse, varscan2
- SLC45A1 | c.984G>A p.S328= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs200823214, COSV57094902; called by muse, mutect2, varscan2
- TTN | c.37539A>G p.K12513= (on ENST00000591111; = p.K5089= on NM_003319.4) | Silent (SNP) | VAF 91/204 reads (45%) | catalogued as rs1042532845, COSV60239359; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502932 ins A | 5'Flank (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- HERC2P3 | n.725T>C | RNA (SNP) | VAF 48/224 reads (21%) | called by muse, mutect2, varscan2
- TMEM183B | n.362A>G | RNA (SNP) | VAF 63/134 reads (47%) | called by muse, mutect2, varscan2
